Gene-level copy-number profile of tumor specimen TARGET-51-PAJLWU-01A from TARGET case TARGET-51-PAJLWU, project TARGET-CCSK (Clear Cell Sarcoma of the Kidney). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell sarcoma of kidney; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 1.6 years (569 days).
Specimen TARGET-51-PAJLWU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-CCSK.3ec89348-1bd7-56d8-8842-1919b2f2d964.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-51-PAJLWU-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 352 have no estimate.
https://portal.gdc.cancer.gov/files/b8677cf7-4d36-43b5-866f-62d2ace5396d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2,389; copy number 1: 179; copy number 2: 57,511; copy number 3: 28; copy number 4: 11; copy number 5: 7; copy number 6: 115; copy number 7: 6; copy number 10: 25.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:16,257,061–16,350,299, 3 genes (within-gene range 0–2): DPH3, OXNAD1, AC090953.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 153 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–88,861,563, 1 gene, copy number 10 (within-gene range 2–10): AC244205.1.
- chr2:88,857,161–89,117,844, 24 genes, copy number 10: IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17.
- chr4:68,509,441–68,670,652, 6 genes, copy number 7: UGT2B29P, UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15.
- chr14:105,785,505–106,443,583, 115 genes, copy number 6 (broad region; genes not listed).
- chr19:47,745,546–47,794,920, 6 genes, copy number 5: NOP53, SNORD23, NOP53-AS1, SELENOW, RPL23AP80, AC008745.1.
- chr21:16,417,139–16,419,080, 1 gene, copy number 5: AP001172.2.

Autosomal genes at a single copy (total copy number 1): 177. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
